Somatic mutation profile of tumor specimen TCGA-13-1483-01A (aliquot TCGA-13-1483-01A-01W-0549-09) from TCGA case TCGA-13-1483, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.2 years (22,342 days).
Specimen TCGA-13-1483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6518e31c-2be3-4107-ab3b-b48b4a8d4ffe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1483-10A (Blood Derived Normal), aliquot TCGA-13-1483-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92493cac-b70b-4b4f-b11e-7ada33c5ef50

The open-access MAF lists 90 somatic variants for this specimen: 71 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 14, In Frame Del 4, Frame Shift Del 4, Nonsense Mutation 4, Intron 3, Splice Site 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 95/155 reads (61%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB2 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57073385; called by mutect2, varscan2
- ADGRF4 | c.1190C>T p.T397I | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV51952396; called by muse, mutect2, varscan2
- ADGRL4 | c.1544T>C p.L515P | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66061679; called by muse, mutect2, varscan2
- ANKFN1 | c.2008C>A p.H670N | Missense Mutation (SNP) | VAF 136/598 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV59447548; called by muse, mutect2, varscan2
- ARMC4 | c.2047A>T p.N683Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV59463572; called by muse, mutect2, varscan2
- ATG4C | c.1312C>A p.L438I | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.223); catalogued as COSV58605604; called by muse, mutect2, varscan2
- CDH12 | c.1910T>A p.L637Q | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV66405570; called by muse, mutect2, varscan2
- CELF3 | c.619T>A p.Y207N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV99310411; called by muse, mutect2, varscan2
- CFAP97 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99703484; called by muse, mutect2
- CLGN | c.1734G>C p.K578N | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV100346667; called by muse, mutect2, varscan2
- COL1A2 | c.3106G>A p.G1036S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as CM070870, COSV99800184; called by muse, mutect2, varscan2
- CSTA | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 62/710 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.047); catalogued as COSV99138683; called by muse, mutect2
- DBX1 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57054069; called by muse, mutect2, varscan2
- DNAJC10 | c.1356T>G p.N452K | Missense Mutation (SNP) | VAF 16/550 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV99899395; called by muse, mutect2
- ECSIT | c.970T>C p.W324R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV52939391; called by muse, mutect2, varscan2
- EPHA10 | c.249C>A p.N83K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100140004; called by muse, mutect2, varscan2
- FBN2 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52513601; called by muse, mutect2, varscan2
- GRIN2A | c.3616C>T p.R1206* | Nonsense Mutation (SNP) | VAF 90/346 reads (26%) | catalogued as rs1555482324, COSV58033202; called by muse, mutect2, varscan2
- HAVCR1 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100208391, COSV59399976; called by muse, mutect2
- IARS2 | c.2175G>C p.K725N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV56959787; called by muse, mutect2, varscan2
- IL17F | c.456C>A p.C152* | Nonsense Mutation (SNP) | VAF 5/150 reads (3%) | catalogued as COSV100277237; called by muse, mutect2
- IL36A | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV52083142; called by muse, varscan2
- ITLN2 | c.550A>G p.N184D | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1184268312, COSV63537768; called by muse, mutect2, varscan2
- IYD | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV57601192; called by muse, mutect2, varscan2
- KANSL2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV63479664; called by muse, mutect2, varscan2
- KDM3B | c.4889G>A p.R1630Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as rs1233840880, COSV100069838; called by muse, mutect2
- KIF1B | c.4512+2T>C p.X1504_splice (on ENST00000377086 / NM_001365952.1; = p.X1458_splice on NM_015074.3) | Splice Site (SNP) | VAF 31/109 reads (28%) | catalogued as COSV55808841; called by muse, mutect2, varscan2
- LATS1 | c.1517C>G p.P506R | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53590972, COSV53596839; called by muse, mutect2, varscan2
- METTL9 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63961757; called by muse, mutect2, varscan2
- MGAT4C | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV100153071; called by muse, mutect2, varscan2
- MYCBP2 | c.12548C>G p.A4183G (on ENST00000357337; = p.A4221G on NM_015057.5) | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.351); catalogued as COSV62019487; called by muse, mutect2
- MYT1L | c.1579G>C p.G527R | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67720434; called by muse, mutect2, varscan2
- NECTIN4 | c.1432A>G p.I478V | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV63512733; called by muse, mutect2, varscan2
- NEXMIF | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 158/810 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV50031276; called by muse, mutect2, varscan2
- NF1 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM054014, COSV62203537; called by muse, mutect2, varscan2
- NLRP14 | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs750614560, COSV55067217; called by muse, mutect2, varscan2
- OLFML1 | c.924G>A p.W308* | Nonsense Mutation (SNP) | VAF 4/93 reads (4%) | catalogued as COSV55075466; called by muse, mutect2
- OR52E4 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57624774; called by muse, mutect2, varscan2
- PDGFRA | c.175T>A p.Y59N | Missense Mutation (SNP) | VAF 113/490 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57268074; called by muse, mutect2, varscan2
- PLA1A | c.1027G>T p.V343L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.147); catalogued as COSV56331809, COSV99846114; called by muse, mutect2, varscan2
- PPP1R12B | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV61117083; called by muse, mutect2, varscan2
- PRKRIP1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs909784907, COSV61350000; called by mutect2, varscan2
- PRUNE2 | c.4573G>C p.A1525P | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.188); catalogued as COSV65041589; called by muse, mutect2, varscan2
- PTPRJ | c.1954T>C p.S652P | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV101395358; called by muse, mutect2
- RANBP17 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV66645808, COSV66650291; called by muse, mutect2, varscan2
- SERPINE3 | c.577T>A p.S193T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as COSV68545321; called by muse, mutect2, varscan2
- SPEN | c.3706G>C p.D1236H | Missense Mutation (SNP) | VAF 136/290 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65361869; called by muse, mutect2, varscan2
- SYT3 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV58896810; called by muse, mutect2, varscan2
- TAF1 | c.2982G>C p.E994D (on ENST00000373790 / NM_138923.4; = p.E1015D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.405); catalogued as COSV99336157; called by muse, mutect2, varscan2
- TCN1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs769073934, COSV57252493; called by muse, mutect2
- TECPR1 | c.2498C>T p.T833I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV101130579; called by muse, mutect2
- TNRC6A | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs776734425, COSV59364290; called by muse, mutect2, varscan2
- TUBB2A | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100373911, COSV61319043; called by muse, mutect2
- UBE3C | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100780004; called by muse, mutect2
- UBR5 | c.6182C>G p.A2061G | Missense Mutation (SNP) | VAF 40/465 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99641284; called by muse, mutect2
- USP38 | c.2573A>G p.Y858C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61025905; called by muse, mutect2, varscan2
- WNT16 | c.817del p.D273Ifs*23 (on ENST00000222462 / NM_057168.2; = p.D263Ifs*23 on NM_016087.2) | Frame Shift Del (DEL) | VAF 68/124 reads (55%) | catalogued as COSV55975778; called by mutect2, pindel, varscan2
- ZDHHC3 | c.487T>G p.C163G | Missense Mutation (SNP) | VAF 59/404 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943489; called by muse, mutect2, varscan2
- ZNF500 | c.562A>T p.R188W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV54788195; called by muse, mutect2, varscan2
- ZNF638 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs774301789, COSV52486551; called by muse, mutect2, varscan2
- ANKRD34A | c.535G>T p.G179W | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- ARMCX5-GPRASP2 | c.1119_1127del p.L373_S375del | In Frame Del (DEL) | VAF 26/250 reads (10%) | called by mutect2, pindel
- COL6A3 | c.3003_3042del p.K1001Nfs*34 | Frame Shift Del (DEL) | VAF 111/482 reads (23%) | called by mutect2, pindel
- CYFIP1 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIDINS220 | c.639_641del p.G214del | In Frame Del (DEL) | VAF 30/104 reads (29%) | called by pindel, varscan2
- LCT | c.4459_4464del p.P1487_Q1488del | In Frame Del (DEL) | VAF 28/96 reads (29%) | called by pindel, varscan2
- MCF2 | c.1953_1979del p.D651_K660delinsE | In Frame Del (DEL) | VAF 86/402 reads (21%) | called by mutect2, pindel, varscan2
- QSOX2 | c.329-9_357del p.X110_splice | Splice Site (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel
- SEPTIN11 | c.726_733del p.E242Dfs*19 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel
- ZBBX | c.1732_1738del p.Q578* | Frame Shift Del (DEL) | VAF 85/263 reads (32%) | called by mutect2, pindel, varscan2
- CIC | c.2211C>A p.A737= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV50571374; called by muse, mutect2, varscan2
- CTNNA3 | c.849A>G p.L283= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as rs762976031, COSV65583321; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTNND1 | c.1773C>T p.H591= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV62383507; called by muse, mutect2, varscan2
- DARS1 | c.82A>C p.R28= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV51538201; called by muse, mutect2, varscan2
- FAM47C | c.894T>C p.P298= | Silent (SNP) | VAF 68/204 reads (33%) | catalogued as COSV63726657; called by muse, mutect2, varscan2
- GDAP1 | c.852G>A p.L284= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV99619679; called by muse, mutect2
- HLCS | c.1614C>T p.I538= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV100358322; called by muse, mutect2
- KDR | c.1653T>A p.P551= | Silent (SNP) | VAF 71/124 reads (57%) | catalogued as COSV55765235; called by muse, mutect2, varscan2
- LRIG1 | c.1740C>T p.T580= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV56240139; called by muse, mutect2, varscan2
- MSR1 | c.1065G>T p.G355= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100027503; called by muse, mutect2, varscan2
- PCMT1 | c.282C>T p.D94= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV66303381; called by muse, mutect2, varscan2
- PDHA1 | c.837C>A p.P279= | Silent (SNP) | VAF 65/253 reads (26%) | catalogued as COSV100134993; called by muse, mutect2, varscan2
- USP37 | c.858A>G p.L286= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV99294570; called by muse, mutect2, varscan2
- ZNF462 | c.3528G>A p.L1176= | Silent (SNP) | VAF 147/409 reads (36%) | catalogued as COSV52938482; called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516706 C>G | 3'Flank (SNP) | VAF 6/16 reads (38%) | catalogued as COSV64597696; called by muse, mutect2
- FABP5P3 | chr7:152446431 T>A | 3'Flank (SNP) | VAF 96/147 reads (65%) | called by muse, mutect2, varscan2
- NECTIN1 | c.1003+536G>A | Intron (SNP) | VAF 53/252 reads (21%) | catalogued as COSV50599828; called by muse, varscan2
- NTRK3 | c.1586-38613C>T | Intron (SNP) | VAF 116/394 reads (29%) | catalogued as COSV58122611; called by muse, mutect2, varscan2
- P4HTM | c.1073+12C>A | Intron (SNP) | VAF 11/42 reads (26%) | catalogued as COSV59086997; called by muse, mutect2, varscan2
